Somatic mutation profile of tumor specimen TCGA-FS-A4F9-06A (aliquot TCGA-FS-A4F9-06A-11D-A24R-08) from TCGA case TCGA-FS-A4F9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.4 years (29,374 days).
Specimen TCGA-FS-A4F9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a108df8f-4093-4b56-8987-ebfb07035358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F9-10A (Blood Derived Normal), aliquot TCGA-FS-A4F9-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a0ed6e6-2029-4180-a00e-0f8b7923f2ac

The open-access MAF lists 536 somatic variants for this specimen: 356 protein-altering or splice-affecting, 171 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 171, Frame Shift Del 25, Nonsense Mutation 23, In Frame Del 6, Intron 4, Splice Region 4, RNA 3, Splice Site 2, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912916, CM920209, COSV58581416, COSV58592685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 81/178 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA4 | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs777239290, COSV64678807; called by muse, mutect2, varscan2
- ACACB | c.5813T>C p.I1938T | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297454252, COSV58148083; called by muse, mutect2, varscan2
- ACSM2B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61660225; called by muse, mutect2, varscan2
- ADAM15 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.232); catalogued as COSV99665311; called by muse, mutect2
- ADAM18 | c.1005T>A p.C335* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV55856221; called by muse, mutect2, varscan2
- ADAM8 | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101291742; called by muse, mutect2, varscan2
- ADAMTS12 | c.3884C>T p.T1295I | Missense Mutation (SNP) | VAF 101/217 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61281905; called by muse, mutect2, varscan2
- ADAMTS2 | c.2087A>C p.K696T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as COSV52395772; called by muse, mutect2, varscan2
- ADAR | c.2687G>A p.G896E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425368, COSV99426678; called by muse, mutect2, varscan2
- ADAR | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99426682; called by muse, mutect2, varscan2
- ADCY10 | c.2635C>T p.L879F | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs1243038342, COSV100896473, COSV63245485; called by muse, mutect2, varscan2
- ADGRE2 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as COSV59696723; called by muse, mutect2, varscan2
- ADGRE5 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV54414709; called by muse, mutect2, varscan2
- ADGRG4 | c.6095C>T p.S2032F | Missense Mutation (SNP) | VAF 68/73 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs145052934, COSV54951114, COSV54964574; called by muse, mutect2, varscan2
- AFM | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs531634253, COSV56919726; called by muse, mutect2, varscan2
- ALG10 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs760229984, COSV56792535; called by muse, mutect2, varscan2
- ALK | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66563527; called by muse, mutect2, varscan2
- AMER1 | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57665999; called by muse, mutect2, varscan2
- ANAPC1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV61979896; called by muse, mutect2, varscan2
- ANKRD11 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757502026, COSV56373314; called by muse, mutect2, varscan2
- ANKRD34A | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV60162156; called by muse, mutect2, varscan2
- AP4B1 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); catalogued as rs1460215345, COSV56727216; called by muse, mutect2, varscan2
- APLP1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs780081746, COSV55702835; called by muse, mutect2, varscan2
- AQP12A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1480260777, COSV61837814; called by muse, mutect2, varscan2
- ARAP1 | c.4270C>T p.P1424S (on ENST00000393609 / NM_001040118.2; = p.P1179S on NM_015242.4) | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61995576; called by muse, mutect2, varscan2
- ARGLU1 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62271978; called by muse, mutect2, varscan2
- ARHGAP39 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs756189068, COSV52770277; called by muse, mutect2, varscan2
- ARID1B | c.3866C>T p.P1289L | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV51682999; called by muse, mutect2, varscan2
- ATF6B | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64352566; called by muse, mutect2, varscan2
- ATP2C2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs764582527, COSV52295348; called by muse, mutect2, varscan2
- ATP8B4 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52712753; called by muse, varscan2
- ATP9A | c.2019T>C p.V673= | Splice Region (SNP) | VAF 26/70 reads (37%) | catalogued as COSV58772694; called by muse, mutect2, varscan2
- ATRNL1 | c.3376C>T p.R1126C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs372851241, COSV58087262; called by muse, mutect2, varscan2
- AXL | c.1616G>A p.G539E (on ENST00000301178 / NM_021913.5; = p.G530E on NM_001699.6) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56564783; called by muse, mutect2, varscan2
- BCAN | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61259968; called by muse, mutect2, varscan2
- BCL9 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as rs1553205140, COSV52350848; called by muse, mutect2, varscan2
- BICRAL | c.2494A>G p.K832E | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV58408754; called by muse, mutect2, varscan2
- BRINP2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV64180724; called by muse, mutect2, varscan2
- BSN | c.7357G>A p.E2453K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs761139816, COSV56528996; called by muse, mutect2, varscan2
- BTBD3 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.059); catalogued as rs752200492, COSV54781518; called by muse, mutect2, varscan2
- C5 | c.4373G>A p.G1458E | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV56332642; called by muse, varscan2
- C6 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV54720065; called by muse, mutect2, varscan2
- C6orf58 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767547213, COSV61666152; called by muse, mutect2, varscan2
- CA3 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53409466; called by muse, mutect2, varscan2
- CACNG7 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV55816451; called by muse, mutect2, varscan2
- CADM2 | c.526G>A p.D176N (on ENST00000407528 / NM_001167674.2; = p.D178N on NM_153184.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV67407950; called by muse, mutect2, varscan2
- CAPRIN2 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV51836015; called by muse, mutect2, varscan2
- CASS4 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV64387308; called by muse, mutect2, varscan2
- CC2D2B | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV60359317; called by muse, mutect2, varscan2
- CCDC141 | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs1347427565, COSV55383422; called by muse, mutect2, varscan2
- CDH12 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66452782; called by muse, mutect2, varscan2
- CDK13 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51707099, COSV99475820; called by muse, mutect2, varscan2
- CDS1 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55691208; called by muse, mutect2, varscan2
- CELSR1 | c.3742C>T p.Q1248* | Nonsense Mutation (SNP) | VAF 41/78 reads (53%) | catalogued as COSV53099380; called by muse, mutect2, varscan2
- CEP170B | c.628C>G p.R210G (on ENST00000453495; = p.R139G on NM_015005.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.758); catalogued as COSV69026858; called by muse, mutect2, varscan2
- CEP70 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53874753; called by muse, mutect2, varscan2
- CER1 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV66604025; called by muse, mutect2, varscan2
- CFAP57 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV65265942; called by muse, mutect2, varscan2
- CFAP58 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV57211222; called by muse, mutect2, varscan2
- CHI3L2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63875007; called by muse, mutect2, varscan2
- CHRM2 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as COSV57766130; called by muse, mutect2, varscan2
- CHRNG | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51473571; called by muse, mutect2, varscan2
- CHST2 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1278972960, COSV58887257; called by muse, mutect2, varscan2
- CHTF18 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV50102751; called by muse, mutect2, varscan2
- CLEC3A | c.469G>C p.A157P (on ENST00000651443; = p.A148P on NM_005752.6) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV55221325, COSV55224026; called by muse, mutect2, varscan2
- CLGN | c.1274A>C p.D425A | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57776712; called by muse, mutect2, varscan2
- CMYA5 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV71409973; called by muse, mutect2, varscan2
- CNTN5 | c.3161G>A p.G1054E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54362001; called by muse, mutect2, varscan2
- COL19A1 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59590154; called by muse, mutect2, varscan2
- COL4A1 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65432722; called by muse, mutect2, varscan2
- COL7A1 | c.6245G>A p.G2082E | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM071640, COSV60403999; called by muse, mutect2, varscan2
- COL9A1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV57881850; called by muse, mutect2, varscan2
- COPS7B | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62601658; called by muse, mutect2, varscan2
- CSDC2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.666); catalogued as rs1374373828, COSV53449628; called by muse, mutect2, varscan2
- CUL7 | c.3895C>T p.R1299C | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759612933, COSV54822634; called by muse, mutect2, varscan2
- CYP2A7 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV52504315; called by muse, mutect2, varscan2
- CYP2C19 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV64908528; called by muse, mutect2, varscan2
- CYTH4 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV50636405; called by muse, mutect2, varscan2
- DACH1 | c.1294C>T p.P432S (on ENST00000619232 / NM_001366712.1; = p.P380S on NM_080759.6) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767288373, COSV57518979; called by muse, mutect2, varscan2
- DCC | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV100500505, COSV59118029; called by muse, mutect2, varscan2
- DDX60 | c.3914_3915del p.V1305Gfs*15 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs1393032762; called by pindel, varscan2
- DHRSX | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV58139895; called by muse, mutect2, varscan2
- DMBT1 | c.7175C>T p.S2392L (on ENST00000338354 / NM_001377530.1; = p.S1635L on NM_004406.3) | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.591); catalogued as COSV57539137; called by muse, mutect2, varscan2
- DNM2 | c.2383C>T p.P795S (on ENST00000355667 / NM_001005360.3; = p.P791S on NM_004945.3) | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as COSV53033423, COSV53035557; called by muse, mutect2, varscan2
- DPP9 | c.2231C>T p.P744L (on ENST00000598800; = p.P773L on NM_139159.5) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53594730; called by muse, mutect2, varscan2
- DSG4 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as COSV57398387; called by muse, mutect2, varscan2
- DYNC1H1 | c.13411G>T p.A4471S | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV64143535; called by muse, mutect2, varscan2
- EAPP | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51653404; called by muse, mutect2, varscan2
- ECHDC3 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV64868027; called by muse, mutect2, varscan2
- EHD2 | c.156C>G p.D52E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs764869867, COSV54411254; called by muse, mutect2, varscan2
- EIF3A | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs372236521; called by muse, mutect2
- ELFN2 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs1398763827, COSV68745113; called by muse, mutect2, varscan2
- ENPEP | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54458260; called by muse, mutect2, varscan2
- ESR2 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1220163606, COSV50839344; called by muse, mutect2, varscan2
- EXOC3 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs774053027, COSV59268408; called by muse, mutect2, varscan2
- F8 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 85/93 reads (91%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV64278640; called by muse, mutect2, varscan2
- FAM13B | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV50370092; called by muse, mutect2, varscan2
- FAM151A | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs188390438, COSV56366592; called by muse, mutect2, varscan2
- FAT3 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53113691; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FBXO42 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65047167; called by muse, mutect2, varscan2
- FCGR2B | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52682563; called by muse, mutect2, varscan2
- FCRL6 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV58942951; called by muse, mutect2, varscan2
- FERMT1 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV54091455; called by muse, mutect2, varscan2
- FILIP1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52741864; called by muse, mutect2, varscan2
- FLG2 | c.4577G>A p.G1526E | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs768124580, COSV66174053; called by muse, mutect2, varscan2
- FMN1 | c.2044C>T p.P682S (on ENST00000616417 / NM_001277313.2; = p.P459S on NM_001103184.4) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57934813; called by muse, mutect2
- FNDC1 | c.4717C>T p.P1573S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs776709795, COSV51948751; called by muse, mutect2, varscan2
- FOXJ2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs1335219999, COSV50825706, COSV99368401; called by muse, mutect2, varscan2
- FOXK2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV58883376; called by muse, mutect2, varscan2
- FOXR2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.21); PolyPhen benign (0.4); catalogued as rs767845474, COSV59259454, COSV59259611; called by muse, mutect2, varscan2
- FYB2 | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs868438698, COSV58589801; called by muse, mutect2, varscan2
- GBP7 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs867870028, COSV54012244; called by muse, mutect2, varscan2
- GDPD5 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV61130570; called by muse, mutect2
- GDPD5 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs1339896120, COSV61130579; called by muse, mutect2
- GFRA3 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV51232117; called by muse, mutect2, varscan2
- GJB5 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58357178; called by muse, mutect2, varscan2
- GPR87 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV53464724; called by muse, mutect2, varscan2
- GPRC6A | c.840A>T p.Q280H | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as COSV59956305; called by muse, mutect2, varscan2
- GRIN2A | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100408175, COSV58053099; called by muse, mutect2, varscan2
- GRM4 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV65220381; called by muse, mutect2, varscan2
- GRM7 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63174243; called by muse, mutect2, varscan2
- HECW2 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53675982; called by muse, mutect2, varscan2
- HPS6 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100155001; called by muse, mutect2, varscan2
- HSPA13 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53466618; called by muse, mutect2, varscan2
- HYDIN | c.12194C>T p.P4065L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV66642751; called by mutect2, varscan2
- HYDIN | c.7201G>A p.E2401K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs772680657, COSV59250071; called by muse, mutect2, varscan2
- IGKV1-27 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs532685739; called by muse, mutect2, varscan2
- IGSF1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV63840333; called by muse, mutect2, varscan2
- IGSF10 | c.6577C>T p.H2193Y | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774456497, COSV56371790; called by muse, mutect2, varscan2
- IKZF2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV59584793; called by muse, mutect2, varscan2
- IL21R | c.650G>A p.W217* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as COSV61972797; called by muse, mutect2, varscan2
- INCA1 | c.599_601del p.E200del (on ENST00000574617 / NM_001167986.1; = p.E185del on NM_213726.2) | In Frame Del (DEL) | VAF 24/34 reads (71%) | catalogued as rs1435344592; called by pindel, varscan2
- IQGAP2 | c.4615G>A p.D1539N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1561618869, COSV57179857; called by muse, mutect2, varscan2
- ITGA2 | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); catalogued as COSV56867306; called by muse, mutect2, varscan2
- ITIH2 | c.62T>A p.I21N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV64435482; called by muse, mutect2, varscan2
- KIAA1217 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1304702089, COSV64614072; called by muse, mutect2, varscan2
- KIAA1841 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV54379336; called by muse, mutect2, varscan2
- KIAA2026 | c.2728A>G p.S910G | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV67358058; called by muse, mutect2, varscan2
- KNSTRN | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV51112457; called by muse, mutect2, varscan2
- KPRP | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as rs547882733, COSV64223115; called by muse, mutect2, varscan2
- KRTAP5-8 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV68324969; called by muse, varscan2
- KSR2 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56684946; called by muse, mutect2, varscan2
- LAMB4 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as COSV52732401; called by muse, mutect2, varscan2
- LCA5L | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV55747585; called by muse, mutect2, varscan2
- LOXL2 | c.2285A>T p.H762L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99743992; called by muse, mutect2, varscan2
- LRRIQ3 | c.1658A>G p.K553R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV63050698; called by muse, mutect2, varscan2
- LRRN3 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57824362; called by muse, mutect2, varscan2
- LUZP2 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61219731; called by muse, mutect2, varscan2
- MAGEA6 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 83/92 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV61449473; called by muse, mutect2, varscan2
- MCC | c.172-1G>A p.X58_splice | Splice Site (SNP) | VAF 28/58 reads (48%) | catalogued as COSV56737097; called by muse, mutect2, varscan2
- MCU | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV64068697; called by muse, mutect2, varscan2
- MGAM | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299819756, COSV72076000; called by muse, mutect2, varscan2
- MGAM | c.5128C>T p.H1710Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV72076001; called by muse, mutect2, varscan2
- MORC1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV51718997, COSV51732652; called by muse, mutect2, varscan2
- MPP2 | c.394G>A p.D132N (on ENST00000461854 / NM_001278372.2; = p.D108N on NM_005374.5) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs934792461, COSV99290804; called by muse, mutect2, varscan2
- MPP7 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289288442, COSV61738971; called by muse, mutect2, varscan2
- MRTFA | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62937263; called by muse, mutect2, varscan2
- MSR1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs868009130, COSV50540534; called by muse, mutect2, varscan2
- MUC16 | c.13166C>T p.T4389I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.412); catalogued as rs866487135, COSV67497960; called by muse, mutect2, varscan2
- MUC16 | c.10439G>A p.G3480E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV67458733; called by muse, mutect2
- MUC4 | c.14161C>T p.Q4721* (on ENST00000463781 / NM_018406.7; = p.Q485* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs762230926, COSV57805537; called by muse, mutect2, varscan2
- MUTYH | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs777335285, CM141207, COSV58345085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MX1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs757747473, COSV55820749; called by muse, mutect2, varscan2
- MYH4 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 56/69 reads (81%) | catalogued as COSV55127395; called by muse, mutect2, varscan2
- MYH8 | c.3255G>A p.K1085= | Splice Region (SNP) | VAF 26/33 reads (79%) | catalogued as COSV67959126; called by muse, mutect2, varscan2
- MYLK3 | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67367173; called by muse, mutect2, varscan2
- NAPA | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV54552211; called by muse, mutect2, varscan2
- NBEA | c.1010G>A p.W337* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV59827209; called by muse, mutect2, varscan2
- NCAPH2 | c.1003A>G p.R335G | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs199558436, COSV52689578; called by muse, mutect2, varscan2
- NDST4 | c.2363T>C p.V788A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV52116408; called by muse, mutect2, varscan2
- NLGN4Y | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 67/77 reads (87%) | catalogued as COSV59300380; called by muse, mutect2, varscan2
- NUP210 | c.3028C>T p.L1010F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV54407208; called by muse, mutect2, varscan2
- NUP210L | c.4611G>A p.M1537I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV55148830; called by muse, mutect2, varscan2
- NXPH2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.011); catalogued as COSV55647347; called by muse, mutect2, varscan2
- OPRD1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV52383732; called by muse, mutect2, varscan2
- OR10G8 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs150048996; called by muse, mutect2, varscan2
- OR10H3 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59944955; called by muse, mutect2, varscan2
- OR13F1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100594851; called by muse, mutect2
- OR2G6 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV58576013; called by muse, mutect2, varscan2
- OR2T12 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58779852; called by muse, mutect2, varscan2
- OR3A3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV52168801; called by muse, mutect2, varscan2
- OR4E2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57731738; called by muse, mutect2, varscan2
- OR4K1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV53458965, COSV99578828; called by muse, mutect2, varscan2
- OR5AC2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62279940; called by muse, mutect2, varscan2
- OR5B12 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1402355071, COSV56904305; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR6K2 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV62744325; called by muse, mutect2, varscan2
- OR7E24 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV71702232, COSV71702374; called by muse, mutect2, varscan2
- OSBPL6 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51931800; called by muse, mutect2, varscan2
- OTC | c.640C>A p.H214N | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as CM961057, COSV50004981; called by muse, mutect2, varscan2
- OVCH2 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as rs775193800, COSV71953012; called by muse, mutect2, varscan2
- OXSR1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1435130969, COSV61260799; called by muse, mutect2, varscan2
- P3H2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1483672350, COSV60028635; called by muse, mutect2, varscan2
- PAGE4 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (1); PolyPhen possibly damaging (0.727); catalogued as COSV54334680, COSV99489855; called by muse, mutect2, varscan2
- PAK5 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV62039193; called by muse, mutect2, varscan2
- PALB2 | c.2852C>T p.S951F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs587782889, COSV55170856; ClinVar: uncertain significance; called by muse, mutect2
- PARD3B | c.3603G>A p.M1201I (on ENST00000406610 / NM_001302769.2; = p.M1132I on NM_057177.7) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs966760480, COSV62532879; called by muse, mutect2, varscan2
- PCDHB3 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV50638949; called by muse, mutect2
- PCNX1 | c.3669C>A p.F1223L | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV53103091; called by muse, mutect2, varscan2
- PCSK5 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV65097452; called by muse, mutect2, varscan2
- PDZD2 | c.3941C>T p.P1314L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV56874470; called by muse, mutect2, varscan2
- PEAK3 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV59233186; called by muse, mutect2, varscan2
- PEX5 | c.1793C>T p.A598V (on ENST00000420616; = p.A590V on NM_000319.5) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV56958867; called by muse, mutect2, varscan2
- PGBD1 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 128/239 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV52556342; called by muse, mutect2, varscan2
- PGM2 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV67939665; called by muse, mutect2, varscan2
- PGM2L1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53350146; called by muse, mutect2, varscan2
- PIK3AP1 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767463653, COSV59537997; called by muse, mutect2, varscan2
- PKD1L2 | c.351T>A p.H117Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs530697033, COSV61411264, COSV61420196; called by muse, mutect2, varscan2
- PLA1A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs757668151, COSV56334070; called by muse, mutect2
- PLEKHG6 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs997658409, COSV50615960; called by muse, mutect2, varscan2
- PMS1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566975683, COSV59717615; called by muse, mutect2, varscan2
- POLR1A | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55700350; called by muse, mutect2, varscan2
- POM121 | c.1763C>T p.S588F (on ENST00000434423; = p.S323F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99989198; called by muse, mutect2, varscan2
- PPT2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV61355337; called by muse, mutect2, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- PSKH2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52612973; called by muse, mutect2, varscan2
- PTPRH | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV54746899; called by muse, mutect2, varscan2
- PURG | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53296960; called by muse, mutect2, varscan2
- RABGAP1L | c.1828T>C p.Y610H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52332176; called by muse, mutect2, varscan2
- RIMS1 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747771359, COSV53442594; called by muse, mutect2, varscan2
- RIT2 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 133/292 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56309961; called by muse, mutect2, varscan2
- RNF17 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.441); catalogued as rs1377002319, COSV55052876; called by muse, mutect2, varscan2
- RNF17 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV55037245; called by muse, mutect2, varscan2
- RNF19B | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99331716; called by muse, mutect2, varscan2
- RNF19B | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99331718; called by muse, mutect2, varscan2
- RP1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV55128231; called by muse, mutect2, varscan2
- RPL35A | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV54562504; called by muse, mutect2, varscan2
- RREB1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254556261, COSV58566546; called by muse, mutect2, varscan2
- RXFP2 | c.711C>T p.F237= | Splice Region (SNP) | VAF 15/20 reads (75%) | catalogued as COSV53640025; called by muse, mutect2, varscan2
- SALL4 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53849946; called by muse, mutect2, varscan2
- SASH1 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as COSV66566548; called by muse, mutect2, varscan2
- SASH3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV63556491; called by muse, mutect2, varscan2
- SCN10A | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV71862771; called by muse, mutect2, varscan2
- SCN2A | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51837026; called by muse, mutect2, varscan2
- SCN7A | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV69272731; called by muse, mutect2, varscan2
- SEPTIN2 | c.987C>T p.L329= | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as rs1295150090, COSV63633609; called by muse, mutect2, varscan2
- SGCG | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54557672, COSV54562563; called by muse, mutect2, varscan2
- SHANK1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs267605596, COSV53263641; called by muse, mutect2, varscan2
- SHANK2 | c.3337G>A p.G1113S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV53621694; called by muse, mutect2, varscan2
- SHROOM3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs746483211, COSV56033263, COSV56039198; called by muse, mutect2, varscan2
- SI | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV52267005; called by muse, mutect2, varscan2
- SIGLEC1 | c.2819C>T p.S940L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs374046659; called by muse, mutect2, varscan2
- SIGLEC5 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV55784503; called by muse, mutect2, varscan2
- SIM2 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1246046128, COSV51773427; called by muse, mutect2, varscan2
- SIPA1L3 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368942102; called by muse, mutect2, varscan2
- SLC12A1 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57712320; called by muse, mutect2, varscan2
- SLC15A1 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV64733959; called by muse, mutect2, varscan2
- SLC17A2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55352136, COSV55353309; called by muse, mutect2, varscan2
- SLC4A10 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55770441, COSV55804080; called by muse, mutect2, varscan2
- SLCO5A1 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52667608; called by muse, mutect2, varscan2
- SLIT1 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867890874, COSV56596870; called by muse, mutect2, varscan2
- SLITRK3 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV99580123; called by muse, mutect2, varscan2
- SLITRK6 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.863); catalogued as rs750992179, COSV68391906; called by muse, mutect2, varscan2
- SMARCA1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 44/48 reads (92%) | catalogued as COSV64414087; called by muse, mutect2, varscan2
- SNRPN | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.857); catalogued as rs71461576, COSV57600982; called by muse, mutect2, varscan2
- SORL1 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV52763627; called by muse, mutect2, varscan2
- SPATA31D1 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV61193478; called by muse, mutect2, varscan2
- SPATA6 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765166760, COSV64056583, COSV64057093; called by muse, mutect2, varscan2
- SPINT4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV54143428; called by muse, mutect2, varscan2
- SPOCD1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV57100456; called by muse, mutect2, varscan2
- SRSF1 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 64/70 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51966567; called by muse, mutect2, varscan2
- SSRP1 | c.1698G>C p.K566N | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV53481953; called by muse, mutect2, varscan2
- ST18 | c.2674G>T p.G892* | Nonsense Mutation (SNP) | VAF 4/69 reads (6%) | catalogued as COSV52511566; called by muse, mutect2
- ST18 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV52485250; called by muse, mutect2, varscan2
- SUSD4 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV59557149, COSV59557241; called by muse, mutect2, varscan2
- SYCP2L | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs267600759, COSV51651688; called by muse, mutect2, varscan2
- SYMPK | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1187715535, COSV55616245; called by muse, mutect2, varscan2
- TANC2 | c.3883C>T p.L1295F | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67342324; called by muse, mutect2, varscan2
- TBC1D5 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866613522, COSV53750594; called by muse, mutect2, varscan2
- TBXT | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV51617105; called by muse, mutect2, varscan2
- TCAF1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV100584712; called by mutect2, varscan2
- TENM1 | c.7702G>A p.E2568K | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs867286210, COSV64445097; called by muse, mutect2, varscan2
- TEX55 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55213080; called by muse, mutect2, varscan2
- TG | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV55096427; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51516762, COSV99304982; called by muse, mutect2
- THEMIS | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV64069513; called by muse, mutect2, varscan2
- TIMD4 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV50861128; called by muse, mutect2, varscan2
- TLL1 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.996); catalogued as COSV50331819; called by muse, mutect2, varscan2
- TLL2 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1313627278, COSV63576401; called by muse, mutect2, varscan2
- TLR8 | c.2386C>T p.P796S (on ENST00000218032 / NM_138636.5; = p.P814S on NM_016610.4) | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54319784, COSV54321204; called by muse, mutect2, varscan2
- TMC5 | c.1267G>A p.E423K (on ENST00000396229 / NM_001105248.1; = p.E177K on NM_024780.5) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV54903373; called by muse, mutect2, varscan2
- TMPRSS15 | c.2723G>A p.R908K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as COSV53043816; called by muse, mutect2, varscan2
- TOR1AIP2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771673669, COSV62627367; called by muse, mutect2, varscan2
- TOX2 | c.491G>A p.G164E (on ENST00000358131 / NM_001098798.2; = p.G113E on NM_032883.3) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.462); catalogued as COSV57896767; called by muse, mutect2, varscan2
- TPK1 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as COSV63649321; called by muse, mutect2, varscan2
- TPP2 | c.2952+1G>T p.X984_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV65755166; called by muse, mutect2, varscan2
- TPST1 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV59180950; called by muse, mutect2, varscan2
- TRHDE | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.062); catalogued as COSV53868313; called by muse, mutect2, varscan2
- TRIM10 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1202872249, COSV65000258; called by muse, mutect2, varscan2
- TRIM10 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 223/305 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV64990549; called by muse, mutect2, varscan2
- TRIM51 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146327492; called by muse, mutect2, varscan2
- TRIM71 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 94/215 reads (44%) | catalogued as COSV67472462; called by muse, mutect2, varscan2
- TSHZ3 | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53684340; called by muse, mutect2, varscan2
- TTN | c.23332C>T p.L7778F (on ENST00000591111; = p.L6851F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | PolyPhen benign (0.165); catalogued as COSV60383687; called by muse, mutect2, varscan2
- TTN | c.21725G>A p.G7242E (on ENST00000591111; = p.G6315E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | PolyPhen probably damaging (0.986); catalogued as COSV59915855; called by muse, mutect2, varscan2
- TTN | c.18549G>A p.M6183I (on ENST00000591111; = p.M5256I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | PolyPhen benign (0.001); catalogued as COSV59862723; called by muse, mutect2, varscan2
- UBE3C | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61955876; called by muse, mutect2, varscan2
- UGT2B15 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs759605240, COSV57733130; called by muse, mutect2, varscan2
- UGT2B4 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV59321153; called by muse, mutect2, varscan2
- UMODL1 | c.354del p.A120Pfs*58 | Frame Shift Del (DEL) | VAF 68/184 reads (37%) | catalogued as COSV68554986; called by mutect2, varscan2
- UNC5D | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54840145; called by muse, mutect2, varscan2
- UNC79 | c.3754C>T p.R1252* (on ENST00000393151 / NM_001346218.2; = p.R1075* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 29/32 reads (91%) | catalogued as rs1253600542, COSV56375172; called by muse, mutect2, varscan2
- UNKL | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746401463, COSV57021497; called by muse, mutect2, varscan2
- USP17L2 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs1300146091, COSV61556859; called by muse, mutect2, varscan2
- USP19 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490168078, COSV60047334; called by muse, mutect2, varscan2
- VCX | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs746647998; called by mutect2, varscan2
- WWC1 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV54659357; called by muse, mutect2, varscan2
- XIRP2 | c.3323C>T p.S1108F (on ENST00000628543; = p.S1283F on NM_152381.6) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54687903, COSV54737839; called by muse, mutect2, varscan2
- XIRP2 | c.6716G>A p.G2239E (on ENST00000628543; = p.G2414E on NM_152381.6) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV54685031; called by muse, mutect2, varscan2
- ZBTB4 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV60984370; called by muse, mutect2, varscan2
- ZBTB7A | c.1124_1126del p.K375del | In Frame Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs1375400999; called by pindel, varscan2
- ZC3H12C | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53707900, COSV53713337; called by muse, mutect2, varscan2
- ZC3H14 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV51773074; called by muse, mutect2, varscan2
- ZC3H7B | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60964983; called by muse, mutect2
- ZDHHC15 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 24/26 reads (92%) | catalogued as COSV64903927; called by muse, mutect2, varscan2
- ZDHHC17 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1306544499, COSV100602174, COSV58351499; called by muse, mutect2, varscan2
- ZMYM1 | c.1673T>A p.I558N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV63254043; called by muse, mutect2, varscan2
- ZNF236 | c.5380A>T p.K1794* | Nonsense Mutation (SNP) | VAF 40/44 reads (91%) | catalogued as COSV53498965; called by muse, mutect2, varscan2
- ZNF428 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV56194028; called by muse, mutect2, varscan2
- ZNF470 | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV57970626; called by muse, mutect2, varscan2
- ABL1 | c.3212_3213del p.V1071Gfs*22 | Frame Shift Del (DEL) | VAF 37/121 reads (31%) | called by pindel, varscan2
- AOC2 | c.1087_1088del p.V363Ifs*18 | Frame Shift Del (DEL) | VAF 60/112 reads (54%) | called by pindel, varscan2
- ARL13B | c.1038_1039del p.K347Nfs*2 (on ENST00000394222 / NM_001174150.2; = p.K240Nfs*2 on NM_144996.4) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- CDAN1 | c.756_757del p.E252Dfs*8 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by pindel, varscan2
- CMTR2 | c.1123_1124del p.I375Ffs*2 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- CTRL | c.255_257del p.V86del | In Frame Del (DEL) | VAF 30/85 reads (35%) | called by pindel, varscan2
- CYB5R4 | c.472_473del p.D158Yfs*8 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- DLC1 | c.4383del p.N1462Mfs*8 (on ENST00000276297 / NM_001348081.2; = p.N1025Mfs*8 on NM_006094.5) | Frame Shift Del (DEL) | VAF 55/122 reads (45%) | called by mutect2, pindel, varscan2
- DOP1A | c.6815_6816del p.V2272Gfs*11 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by pindel, varscan2
- EIF2AK2 | c.1163_1164del p.K388Sfs*8 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- FRG2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by mutect2, varscan2
- HIVEP1 | c.1676_1677del p.E559Vfs*17 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by pindel, varscan2
- HOXD8 | c.628_629del p.L210Rfs*9 | Frame Shift Del (DEL) | VAF 72/222 reads (32%) | called by pindel, varscan2
- ITGA10 | c.404_405del p.S135Cfs*48 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by pindel, varscan2
- KIR2DL3 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 128/646 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MAP4K4 | c.3480_3481del p.E1160Dfs*48 (on ENST00000347699 / NM_001242559.2; = p.E1086Dfs*48 on NM_004834.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | called by pindel, varscan2
- MCOLN2 | c.626_628del p.S209del | In Frame Del (DEL) | VAF 17/65 reads (26%) | called by pindel, varscan2
- OR4A15 | c.731_732del p.V244Gfs*22 | Frame Shift Del (DEL) | VAF 52/208 reads (25%) | called by pindel, varscan2
- POTEA | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRKAR1A | c.1134_1137del p.V381Efs*59 | Frame Shift Del (DEL) | VAF 33/42 reads (79%) | called by mutect2, pindel, varscan2
- PSIP1 | c.896_897del p.R299Kfs*9 | Frame Shift Del (DEL) | VAF 50/77 reads (65%) | called by mutect2, pindel, varscan2
- R3HDM1 | c.665_666del p.S222Cfs*7 | Frame Shift Del (DEL) | VAF 36/119 reads (30%) | called by mutect2, pindel, varscan2
- RPL5 | c.143_146dup p.Y49* | Frame Shift Ins (INS) | VAF 30/63 reads (48%) | called by mutect2, pindel, varscan2
- SEC24A | c.516_518del p.Q172_Y173delinsH | In Frame Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- SPINT1 | c.1047_1048del p.D349Efs*6 (on ENST00000344051 / NM_181642.3; = p.D333Efs*6 on NM_003710.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- TMEM18 | c.386_387del p.R129Kfs*112 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- TP53 | c.825_826del p.A276Lfs*29 | Frame Shift Del (DEL) | VAF 13/24 reads (54%) | called by pindel, varscan2
- VCX3A | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by mutect2, varscan2
- ZGRF1 | c.3983_3994del p.I1328_Y1331del | In Frame Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- ZNF226 | c.548_549del p.R183Ifs*12 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by pindel, varscan2
- ZNF260 | c.507_508del p.C169Wfs*12 | Frame Shift Del (DEL) | VAF 72/220 reads (33%) | called by pindel, varscan2
- ZNF512B | c.1272_1273del p.K425Nfs*25 | Frame Shift Del (DEL) | VAF 98/258 reads (38%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.963G>A p.E321= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV68344696; called by muse, mutect2, varscan2
- AC008676.3 | c.171G>A p.T57= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs746101731, COSV56635988; called by muse, mutect2, varscan2
- ADAM8 | c.1686G>A p.G562= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV101291741; called by muse, mutect2, varscan2
- ADCY6 | c.3175C>T p.L1059= | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as COSV57170954; called by muse, mutect2, varscan2
- ADGRG7 | c.1435T>C p.L479= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV56301850; called by muse, mutect2, varscan2
- ALPK2 | c.1098C>T p.F366= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs762606578, COSV64496753; called by muse, mutect2, varscan2
- ANKRD50 | c.1455C>T p.S485= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV72386377; called by muse, mutect2, varscan2
- AQP10 | c.480C>T p.F160= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs867034814, COSV61476174; called by muse, mutect2, varscan2
- ASZ1 | c.1071C>T p.L357= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as COSV52916833; called by muse, mutect2, varscan2
- ATF7IP | c.2166A>G p.S722= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV53778774; called by muse, mutect2, varscan2
- ATP13A5 | c.825G>A p.E275= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV60876227; called by muse, mutect2, varscan2
- BACE2 | c.1398C>T p.P466= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV57744249; called by muse, mutect2, varscan2
- BDP1 | c.5559C>T p.T1853= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV62435314; called by muse, mutect2, varscan2
- BFSP1 | c.684C>T p.G228= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV64902094; called by muse, mutect2, varscan2
- C12orf71 | c.672C>T p.I224= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV70282920; called by muse, mutect2, varscan2
- C1orf87 | c.576C>T p.S192= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV100967202, COSV64599084; called by muse, mutect2, varscan2
- C9 | c.780C>T p.S260= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54682104; called by muse, mutect2, varscan2
- CA1 | c.183C>T p.I61= | Silent (SNP) | VAF 92/191 reads (48%) | catalogued as COSV56280249, COSV99810171; called by muse, mutect2, varscan2
- CA6 | c.237C>T p.P79= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV101077285, COSV66262977; called by muse, mutect2, varscan2
- CACNA1I | c.4701C>T p.T1567= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs766364324, COSV100361512, COSV60819523; called by muse, mutect2, varscan2
- CASKIN1 | c.369C>T p.A123= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs926651943, COSV58877633; called by muse, mutect2, varscan2
- CASR | c.999C>T p.F333= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs771072628, COSV56136391; called by muse, mutect2, varscan2
- CATSPER3 | c.654C>T p.F218= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV50950695; called by muse, mutect2
- CD226 | c.991A>C p.R331= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV54616546; called by muse, mutect2, varscan2
- CES5A | c.1131C>T p.I377= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs769138677, COSV51871364; called by muse, mutect2, varscan2
- CFAP52 | c.1449G>A p.G483= | Silent (SNP) | VAF 27/33 reads (82%) | catalogued as rs1323122240, COSV55350097; called by muse, mutect2, varscan2
- CLVS2 | c.348G>A p.R116= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV51569514; called by muse, mutect2, varscan2
- COL2A1 | c.2217C>T p.P739= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs772421531, COSV61534977; called by muse, mutect2, varscan2
- CPN2 | c.1078C>T p.L360= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV60472257; called by muse, mutect2, varscan2
- CRB1 | c.1575C>T p.F525= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV66334393; called by muse, mutect2, varscan2
- CST8 | c.132C>T p.N44= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as rs150145986, COSV99849961; called by muse, mutect2, varscan2
- CTTNBP2NL | c.607C>T p.L203= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV54747424; called by muse, mutect2, varscan2
- DDC | c.873G>A p.V291= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV63568167; called by muse, mutect2, varscan2
- DFFB | c.672C>T p.F224= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58861898; called by muse, mutect2, varscan2
- DGAT1 | c.583C>T p.L195= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100184137, COSV60049476; called by muse, mutect2, varscan2
- DGKB | c.1830C>T p.F610= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV51823175; called by muse, mutect2, varscan2
- DNAH8 | c.10593G>A p.K3531= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV59443201, COSV99046881; called by muse, mutect2, varscan2
- DRD1 | c.1107G>A p.A369= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as rs374239045; called by muse, mutect2, varscan2
- DYRK1A | c.762C>T p.F254= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV58297414; called by muse, mutect2, varscan2
- ELOVL7 | c.702G>A p.Q234= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs749778784, COSV70918774; called by muse, mutect2, varscan2
- ENPEP | c.369C>T p.I123= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as COSV54458272; called by muse, mutect2, varscan2
- EPM2A | c.372C>T p.L124= | Silent (SNP) | VAF 33/37 reads (89%) | catalogued as COSV100837492, COSV62298014; called by muse, mutect2, varscan2
- ETF1 | c.516C>T p.F172= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as COSV62127900, COSV62128227; called by muse, mutect2, varscan2
- EVPL | c.1764G>A p.K588= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as COSV56914959, COSV56916680; called by muse, mutect2, varscan2
- FBXL18 | c.1518C>T p.I506= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV66107743; called by muse, mutect2, varscan2
- FCHO1 | c.2382G>T p.V794= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs1440973695, COSV53182535, COSV53185828; called by muse, mutect2, varscan2
- FCRL5 | c.318C>T p.I106= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV62520941; called by muse, mutect2, varscan2
- FER1L6 | c.5523C>T p.F1841= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV67550086; called by muse, mutect2, varscan2
- FLRT1 | c.1185G>A p.T395= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs760054105, COSV55357085; called by muse, mutect2, varscan2
- FRAS1 | c.6660C>T p.T2220= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV53652843; called by muse, mutect2, varscan2
- FRMPD1 | c.156C>T p.I52= | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as COSV63384029; called by muse, mutect2, varscan2
- GAD2 | c.615C>T p.F205= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV52169673; called by muse, mutect2, varscan2
- GBP4 | c.1434C>T p.F478= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV63256221; called by muse, mutect2, varscan2
- GPATCH1 | c.2364C>T p.F788= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV50129414; called by muse, mutect2, varscan2
- GPR137 | c.399C>T p.S133= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV57404193; called by muse, mutect2, varscan2
- GRM7 | c.2520A>C p.L840= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs140754490, COSV63174263; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1833C>T p.S611= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as rs868953010, COSV56092413; called by muse, mutect2, varscan2
- GUCA1C | c.198G>A p.T66= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as rs1365357510, COSV51732639; called by muse, mutect2, varscan2
- HIVEP3 | c.6465C>T p.S2155= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV56024758; called by muse, mutect2, varscan2
- HKDC1 | c.1959C>T p.V653= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as rs201101555, COSV63579748; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1011T>C p.G337= (on ENST00000354667 / NM_031243.3; = p.G325= on NM_002137.4) | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV61161402; called by muse, mutect2, varscan2
- HPS6 | c.588C>T p.S196= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs775911171, COSV100155004; called by muse, mutect2, varscan2
- HTR2C | c.642C>T p.F214= | Silent (SNP) | VAF 170/187 reads (91%) | catalogued as rs368641796, COSV52202768, COSV52205141; called by muse, mutect2, varscan2
- IFNA10 | c.192G>A p.E64= | Silent (SNP) | VAF 72/194 reads (37%) | catalogued as COSV53332421; called by muse, mutect2, varscan2
- IGFL4 | c.63A>C p.G21= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV66619094; called by muse, mutect2, varscan2
- IGHV3-49 | c.27C>T p.F9= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs782399286; called by muse, mutect2, varscan2
- IGKV1D-33 | c.129C>T p.I43= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV101134086; called by muse, mutect2, varscan2
- IQCH | c.567G>A p.Q189= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs775083091, COSV60060800; called by muse, mutect2, varscan2
- IRAG2 | c.3447C>T p.I1149= (on ENST00000636465; = p.I194= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV63141092; called by muse, mutect2, varscan2
- ITIH5 | c.1314C>T p.I438= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs756084635, COSV53667230; called by muse, varscan2
- KCND3 | c.198G>A p.L66= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV56190620; called by muse, mutect2, varscan2
- KRTAP9-9 | c.465C>T p.F155= | Silent (SNP) | VAF 83/100 reads (83%) | catalogued as COSV67454325; called by muse, mutect2, varscan2
- LETM1 | c.1635C>T p.I545= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs374644730, COSV100245125; called by muse, mutect2, varscan2
- LOXL2 | c.2286C>T p.H762= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99743990; called by muse, mutect2, varscan2
- LRRC32 | c.672C>T p.D224= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs766918387, COSV52636057; called by muse, mutect2, varscan2
- LZTR1 | c.2052C>T p.I684= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV53152248; called by muse, mutect2, varscan2
- MAMDC2 | c.273G>A p.S91= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs769565950, COSV65860957; called by muse, mutect2, varscan2
- MIB2 | c.1141C>T p.L381= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1364286502, COSV61757696; called by muse, mutect2, varscan2
- MON1B | c.1566T>C p.R522= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as COSV50254304; called by muse, mutect2, varscan2
- MRI1 | c.468C>T p.A156= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV50005717; called by muse, mutect2, varscan2
- MROH5 | c.2352C>T p.L784= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1471929231, COSV71303032; called by muse, mutect2, varscan2
- MROH5 | c.90C>T p.P30= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs768691163, COSV71302178; called by muse, mutect2, varscan2
- MTO1 | c.723C>T p.P241= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs775450916, COSV64775139; called by muse, mutect2, varscan2
- MTOR | c.2760C>T p.S920= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as rs1423935789, COSV63879022; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.28494G>A p.E9498= | Silent (SNP) | VAF 72/165 reads (44%) | catalogued as COSV67497949; called by muse, mutect2
- MYH4 | c.1338C>T p.I446= | Silent (SNP) | VAF 105/119 reads (88%) | catalogued as COSV55127386; called by muse, mutect2, varscan2
- MYO3A | c.858C>T p.F286= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV56321236; called by muse, mutect2, varscan2
- NCAM1 | c.1422G>A p.L474= (on ENST00000316851 / NM_181351.5; = p.L464= on NM_000615.7) | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV57526033; called by muse, mutect2, varscan2
- NDST1 | c.882C>T p.F294= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs375114031; called by muse, mutect2, varscan2
- NEK10 | c.921C>T p.L307= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs1227184923, COSV58290146; called by muse, mutect2, varscan2
- NPSR1 | c.447C>A p.A149= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV62208301; called by muse, mutect2, varscan2
- NRP1 | c.624C>T p.Y208= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs1390629761, COSV55178496; called by muse, mutect2, varscan2
- OR10J3 | c.408C>T p.I136= | Silent (SNP) | VAF 62/107 reads (58%) | catalogued as COSV59954970; called by muse, mutect2, varscan2
- OR2D2 | c.138C>T p.I46= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as rs371872218; called by muse, varscan2
- OR2L8 | c.180C>T p.F60= | Silent (SNP) | VAF 169/392 reads (43%) | catalogued as COSV61728485; called by muse, mutect2, varscan2
- OR2Y1 | c.681G>A p.V227= | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as COSV57138050; called by muse, mutect2, varscan2
- OR4K2 | c.732C>T p.F244= | Silent (SNP) | VAF 64/260 reads (25%) | catalogued as rs141738617, COSV53849732; called by muse, mutect2, varscan2
- OR8D2 | c.204C>T p.F68= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV62489163; called by muse, mutect2, varscan2
- OR8H2 | c.891G>A p.V297= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as rs267602990, COSV57945515; called by muse, mutect2, varscan2
- OR9Q2 | c.855G>A p.L285= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV61112148; called by muse, mutect2
- OSER1 | c.567C>T p.S189= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV54854898; called by muse, mutect2, varscan2
- PCDHB7 | c.1758G>A p.V586= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2
- PCDHB8 | c.1761G>A p.V587= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as COSV99177344; called by muse, mutect2, varscan2
- PCDHGA4 | c.237C>T p.I79= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV54044537; called by muse, mutect2, varscan2
- PCDHGB3 | c.1651T>C p.L551= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV54044569; called by muse, mutect2, varscan2
- PCNX2 | c.4515C>T p.I1505= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV50919262; called by muse, mutect2, varscan2
- PEG3 | c.4572G>A p.L1524= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV55649468; called by muse, mutect2, varscan2
- PGAM4 | c.471G>A p.K157= | Silent (SNP) | VAF 78/85 reads (92%) | catalogued as COSV58455079; called by muse, mutect2, varscan2
- PGF | c.129C>T p.F43= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as COSV53127427; called by muse, mutect2, varscan2
- PGS1 | c.1155C>T p.T385= | Silent (SNP) | VAF 43/52 reads (83%) | catalogued as COSV53146237, COSV53149030; called by muse, mutect2, varscan2
- PI3 | c.231C>T p.P77= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV54783600; called by muse, mutect2, varscan2
- PKHD1 | c.11580C>T p.I3860= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs1198972125, COSV64401474; called by muse, mutect2, varscan2
- PROX1 | c.1260C>T p.P420= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as COSV54778915; called by muse, mutect2, varscan2
- PRSS58 | c.381C>T p.I127= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV73488884; called by muse, mutect2, varscan2
- PTPRK | c.1323C>T p.D441= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as COSV63908384; called by muse, mutect2, varscan2
- RBBP6 | c.4839G>A p.K1613= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV60508163; called by muse, mutect2, varscan2
- RFX6 | c.1416G>A p.V472= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV60589165; called by muse, mutect2, varscan2
- RPGRIP1L | c.2493C>T p.P831= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV50919141; called by muse, mutect2, varscan2
- RSPH4A | c.1563T>C p.N521= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs143732959; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RUSC2 | c.693C>T p.L231= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as COSV63430773; called by muse, mutect2, varscan2
- SAMD9L | c.4377C>T p.F1459= | Silent (SNP) | VAF 86/179 reads (48%) | catalogued as COSV59080080; called by muse, mutect2, varscan2
- SBF1 | c.3525C>T p.V1175= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV62370755; called by muse, mutect2, varscan2
- SCAMP3 | c.828C>T p.S276= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV56944504; called by muse, mutect2, varscan2
- SCN1A | c.3741G>A p.T1247= (on ENST00000303395 / NM_001202435.3; = p.T1236= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs200745708, COSV57684225; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.4152C>T p.L1384= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs377421402; called by muse, mutect2, varscan2
- SIGLEC1 | c.3546G>A p.E1182= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs967046640, COSV52474176; called by muse, mutect2, varscan2
- SIK3 | c.2806C>T p.L936= (on ENST00000445177 / NM_001366686.2; = p.L894= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV52620742, COSV52623995; called by muse, mutect2, varscan2
- SLC12A6 | c.1414T>C p.L472= (on ENST00000354181 / NM_001365088.1; = p.L421= on NM_005135.2) | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV51632809; called by muse, mutect2, varscan2
- SLC14A2 | c.408C>T p.L136= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as rs757323552, COSV54915118; called by muse, mutect2, varscan2
- SLC22A25 | c.522C>T p.F174= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs763533661, COSV60599760; called by muse, mutect2, varscan2
- SLC22A7 | c.1527C>T p.A509= (on ENST00000372585 / NM_153320.2; = p.A507= on NM_006672.3) | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs1430061169, COSV51484964, COSV51486367; called by muse, mutect2, varscan2
- SLC35G5 | c.987C>T p.S329= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV55311498, COSV55315560; called by muse, mutect2, varscan2
- SLC38A3 | c.1149C>T p.I383= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs587721992, COSV68844190; called by muse, mutect2, varscan2
- SLC4A9 | c.75G>A p.L25= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV50193790; called by muse, mutect2, varscan2
- SLC6A9 | c.1971C>T p.A657= (on ENST00000360584 / NM_201649.4; = p.A603= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 80/182 reads (44%) | catalogued as COSV62212339; called by muse, mutect2, varscan2
- SLITRK3 | c.1944G>A p.G648= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99580120; called by muse, mutect2, varscan2
- SMARCA2 | c.501C>T p.P167= | Silent (SNP) | VAF 41/50 reads (82%) | catalogued as COSV61812416; called by muse, mutect2, varscan2
- SPATA31D1 | c.1740C>T p.S580= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs757667660, COSV100783039; called by muse, mutect2, varscan2
- SPINK6 | c.210A>G p.G70= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV57779194; called by muse, mutect2, varscan2
- SPOCD1 | c.1458G>A p.G486= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs746704608, COSV57100469; called by muse, mutect2, varscan2
- STAB2 | c.5445G>A p.V1815= | Silent (SNP) | VAF 70/83 reads (84%) | catalogued as rs1277847709, COSV66344165, COSV66348055; called by muse, mutect2, varscan2
- SYCP2 | c.453C>T p.F151= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV62766054; called by muse, mutect2, varscan2
- SYTL2 | c.2478G>A p.R826= (on ENST00000528231 / NM_001162951.2; = p.R802= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV60356684; called by muse, mutect2, varscan2
- SZT2 | c.546C>T p.F182= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs781292135, COSV100726326; called by muse, mutect2, varscan2
- TAS2R40 | c.927G>A p.R309= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs76255203; called by muse, mutect2, varscan2
- TERT | c.3096C>T p.F1032= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs757204201, COSV57228603; called by muse, mutect2, varscan2
- THBS1 | c.2901C>A p.P967= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV52956296; called by muse, mutect2, varscan2
- TLL1 | c.903G>A p.R301= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs757580549, COSV50272544, COSV50331739; called by muse, mutect2, varscan2
- TMEM213 | c.282G>A p.L94= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1277988450, COSV59481100; called by muse, mutect2, varscan2
- TMPRSS15 | c.2391C>T p.P797= | Silent (SNP) | VAF 61/148 reads (41%) | catalogued as COSV53050328; called by muse, mutect2, varscan2
- TNFAIP3 | c.1335C>T p.P445= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV52802724; called by muse, mutect2, varscan2
- TP73 | c.708C>T p.V236= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs771419405, COSV60706608; called by muse, mutect2, varscan2
- TRIP11 | c.5376C>T p.F1792= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV50967602; called by muse, mutect2, varscan2
- TSGA10IP | c.489G>A p.K163= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV73245445; called by muse, mutect2, varscan2
- TTC9C | c.393C>T p.L131= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs774905674, COSV53666838; called by muse, mutect2
- TTN | c.15261G>A p.R5087= (on ENST00000591111; = p.R4160= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV60247173; called by muse, mutect2, varscan2
- UGT8 | c.624C>T p.S208= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV60421485; called by muse, mutect2, varscan2
- URB2 | c.4167C>T p.I1389= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV51056603; called by muse, mutect2, varscan2
- VAMP7 | c.249G>A p.K83= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as COSV52901471, COSV52903206; called by muse, mutect2, varscan2
- VAV1 | c.279C>T p.L93= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV58392278; called by muse, mutect2, varscan2
- WDR27 | c.2106C>T p.I702= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs777006582, COSV61216839; called by muse, mutect2, varscan2
- WDR93 | c.129C>T p.L43= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as rs376601121; called by muse, mutect2, varscan2
- WFS1 | c.2631C>T p.F877= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs370347920; ClinVar: likely benign; called by muse, mutect2, varscan2
- XAB2 | c.1287G>A p.V429= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1023458383, COSV50371973; called by muse, mutect2, varscan2
- XIRP2 | c.3924G>A p.Q1308= (on ENST00000628543; = p.Q1483= on NM_152381.6) | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV54737850; called by muse, mutect2, varscan2
- ZCCHC14 | c.2028G>A p.L676= (on ENST00000268616; = p.L813= on NM_015144.3) | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as COSV51890782; called by muse, mutect2, varscan2
- ZFR2 | c.1569G>A p.R523= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53603826; called by muse, mutect2, varscan2
- ZNF507 | c.151T>C p.L51= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV61333615; called by muse, mutect2, varscan2
- ZNF831 | c.2694G>A p.G898= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs758408094, COSV64045792; called by muse, mutect2, varscan2
- ZNF84 | c.2007C>T p.H669= | Silent (SNP) | VAF 90/118 reads (76%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.516G>A p.E172= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56608938; called by muse, mutect2, varscan2
- AC074085.2 | n.317C>T | RNA (SNP) | VAF 54/109 reads (50%) | catalogued as rs267601253; called by muse, mutect2, varscan2
- CRELD2 | c.593-314C>T | Intron (SNP) | VAF 13/17 reads (76%) | catalogued as COSV58208624; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163890 G>A | 5'Flank (SNP) | VAF 31/127 reads (24%) | catalogued as rs1442253206; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2416G>A | RNA (SNP) | VAF 13/24 reads (54%) | catalogued as rs1207095093; called by muse, mutect2, varscan2
- SPTBN1 | c.148+32241C>T | Intron (SNP) | VAF 63/140 reads (45%) | catalogued as COSV100443277; called by muse, mutect2, varscan2
- TCF3 | c.1823-435C>T | Intron (SNP) | VAF 20/49 reads (41%) | catalogued as rs759261756, COSV99514523; called by muse, mutect2, varscan2
- TTN | c.10361-5165G>A | Intron (SNP) | VAF 55/108 reads (51%) | catalogued as rs146359866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2AF1L4 | c.*91C>T | 3'UTR (SNP) | VAF 39/85 reads (46%) | catalogued as COSV53076922; called by muse, mutect2, varscan2
- UBTFL2 | n.376C>T | RNA (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
